Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A9DI, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A9DI-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:

MR #:

BILLING #:

LOCATION:

AGE:

SEX: M

DOB:

PHYSICIAN:

COPY TO:

SURG PATH #:

SPECIMEN CLASS:

ALT ID #:

DATE OF PROCEDURE:

DATE RECEIVED:

TIME RECEIVED:

DATE OF REPORT:

DATE OF PRINTING:

Material Received:

- A: left pelvic lymph node
- B: right pelvic lymph node
- C: prostate
- D: Hernia sac

ICD O 3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
7-5 6/5/14

History:

-year-old male with prostate cancer.

Final Diagnosis:

- A. Lymph nodes (4), "left pelvic lymph node", biopsy:
There is no evidence of malignancy (0/4).
- B. Lymph node (1), "right pelvic lymph node", biopsy:
There is no evidence of malignancy (0/1).
- C. Prostate, "prostate", prostatectomy:
Prostatic adenocarcinoma, poorly differentiated, Gleason grade 5 + 4 (score 9), with invasion of seminal vesicles, extraprostatic extension, and bilateral involvement of 60% of the tissue submitted. See comment.
- D. Mesothelial lined fibrous tissue, "hernia sac", excision:
Hernia sac.

Comment:

Prostate

Procedure: Robotic-assisted laparoscopic prostatectomy.

Histologic Type: Adenocarcinoma.

Histologic Grade: Poorly differentiated.

Gleason Pattern

Primary Pattern: 5

Secondary Pattern: 4

Tertiary Pattern (if higher than primary and secondary): n/a

Total Gleason Score (Primary + Secondary): 9

Proportion (percent) of prostate involved by tumor: 60%

Tumor Multicentricity: No.

Extraprostatic Extension: Yes, near base of left posterior lobe.

Seminal Vesicle Invasion: Yes, bilateral.

Margins: Not involved by tumor.

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
NAME:
MR #:

SURG PATH #:
ALT ID #:

Perineural Invasion: Yes.
Vascular Invasion: Present
Additional Pathologic Findings: None.
Lymph Nodes:
Number Examined: 5
Number Involved: 0
Gross Picture Taken: No.
Pathologic Staging: pT3b N0 Mx

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at _____ this case has been concurrently reviewed by the following pathologist: Dr. _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "left pelvic lymph node" are four palpable lymph nodes ranging in size from 2.5 x 1.5 x 0.6 cm to 0.9 x 0.5 x 0.2 cm. The specimen is submitted as follows:

A1FS, one lymph (trisected)

A2FS, one lymph, one lymph node inked black and one lymph node inked green

The specimen is submitted entirely in A1FS and A2FS.

B. Received fresh labeled with the patient's name and "right pelvic lymph node" is one matted lymph node measuring 5.5 x 1.2 x 0.6 cm. The specimen is sectioned into four pieces and submitted entirely in cassettes B1FS and B2FS.

C. Received in formalin labeled with the patient's name and "prostate-cancer study" is a 39 gram prostate measuring 4.3 cm from right to left, 3.0 cm from anterior to posterior and 4.0 cm from superior to inferior. The right seminal vesicle measures 1.4 x 1 x 0.5 cm. The right vas deferens measures 1.5 cm in length and 0.7 cm in diameter. The left vas deferens measures 1.8 cm in length and 0.7 cm in diameter and the left seminal vesicle measures 1.3 cm x 0.8 cm x 0.5 cm. There is a polypoid protrusion from the otherwise oval prostate located at the bladder neck margin. The protruding tissue measures 1.5 x 1.3 x 1.2 cm. Two core biopsies with a diameter of 0.5 cm have been removed from the right and left posterior lobes of the prostate and submitted for the tissue bank study. The right side of the prostate is inked black and the left side is inked blue. The specimen is serially sectioned to reveal an enlarged left anterior and left posterior lobe of the prostate with a tan-yellow multinodular appearance with nodules ranging in size from 0.8 x 0.7 to 1.0 x 0.7 cm. The remainder of the cut surface is unremarkable. The specimen is submitted as follows:

C1-C2 -	Right bladder neck margin
C3-C4 -	Left bladder neck margin
C5 -	Right distal urethral margin
C6 -	Left distal urethral margin
C7 -	Right seminal vesicle margin
C8 -	Left seminal vesicle margin
C9 -	Right mid anterior lobe (representative section)
C10 -	Left mid anterior lobe (representative section)
C11-C20-	Right posterior lobe (entirely submitted)
C21-C30 -	Left posterior lobe (entirely submitted)

D. Received in formalin labeled with the patient's name and "hernia sac" is a 1.5 x 1.0 x 0.7 cm oval piece of tan-pink soft tissue. The specimen is trisected and submitted entirely in D1.

MR #:

Page 2 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Intraoperative Consultation:

A1FS, lymph node (4), "left pelvic lymph node", biopsy:
Negative for malignancy.

B1FS and B2FS, lymph node (1), "right pelvic lymph node", biopsy:
Negative for malignancy.
MD, Attending Physician

MR #:

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 0bdb4380-acfa-4fe2-a3d4-77237d49e8fe (TCGA-XJ-A9DI.8D5547ED-4864-4CE1-87D0-2FE7621B9B7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).